Somatic mutation profile of tumor specimen MP2PRT-PASKVY-TMP1-A (aliquot MP2PRT-PASKVY-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASKVY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,194 days).
Specimen MP2PRT-PASKVY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5bbbb1a-5689-45b6-81b5-54ccbd46cb79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKVY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKVY-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2878d65f-ae8d-4229-baa8-27aaa6ed21e9

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD12B | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.079); catalogued as rs1467966482; called by muse, mutect2
- COL9A1 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV61827922; called by muse, mutect2
- IL6R | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1036259781; called by muse, mutect2, varscan2
- OR13C8 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as rs79042036; called by muse, mutect2, varscan2
- PGM5 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs199507147; called by muse, mutect2, varscan2
- PPP2R2C | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs747639231, COSV59442406; called by muse, mutect2, varscan2
- TRPC7 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1338221982, COSV61458314; called by muse, mutect2, varscan2
- UNC13C | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV52852472; called by muse, mutect2, varscan2
- VAX1 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99524037; called by muse, mutect2
- YIPF7 | c.839T>C p.F280S | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753490719; called by muse, mutect2, varscan2
- ZNF254 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61644083; called by muse, mutect2, varscan2
- CYP17A1 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYSLTR1 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHV3-30 | chr14:106335080 TCTTTCGCACAGTAATACACA>AG | Missense Mutation (DEL) | VAF 58/263 reads (22%) | called by pindel, varscan2*
- LONRF3 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LRRC36 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- LUC7L3 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 93/250 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB6B | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- MFSD10 | c.1118_1119insAC p.A374Pfs*31 | Frame Shift Ins (INS) | VAF 60/380 reads (16%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.9283T>A p.S3095T | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POLR3B | c.3028C>G p.Q1010E | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP4R3C | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF11 | c.1323G>A p.M441I | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2
- PURG | c.65del p.G22Afs*4 | Frame Shift Del (DEL) | VAF 82/407 reads (20%) | called by mutect2, pindel, varscan2
- SFTPD | c.222A>T p.Q74H | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBA2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- COL6A3 | c.7731C>T p.F2577= | Silent (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- MBTPS1 | c.180C>T p.F60= | Silent (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- NWD2 | c.1986T>C p.L662= | Silent (SNP) | VAF 46/278 reads (17%) | called by muse, mutect2, varscan2
- SLC47A2 | c.270G>A p.S90= | Silent (SNP) | VAF 34/392 reads (9%) | catalogued as rs376857912; called by muse, mutect2
- SYNPO | c.2388C>T p.N796= (on ENST00000394243 / NM_001166208.2; = p.N552= on NM_007286.6) | Silent (SNP) | VAF 30/616 reads (5%) | catalogued as rs138232729; called by muse, mutect2
- UBA2 | c.987G>A p.L329= | Silent (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- UBA2 | c.1209G>A p.L403= | Silent (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- SERF2 | c.*12C>T | 3'UTR (SNP) | VAF 22/336 reads (7%) | catalogued as COSV51049542; called by muse, mutect2
- SLC4A4 | c.1903+151C>G | Intron (SNP) | VAF 9/203 reads (4%) | called by muse, mutect2
